Somatic mutation profile of tumor specimen TCGA-A5-A2K7-01A (aliquot TCGA-A5-A2K7-01A-11D-A17W-09) from TCGA case TCGA-A5-A2K7, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage II; Tumor grade: G3; Age at diagnosis: 41.0 years (14,980 days).
Specimen TCGA-A5-A2K7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6efeb59-763d-454d-b1f2-ff67925a49e6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A5-A2K7-10A (Blood Derived Normal), aliquot TCGA-A5-A2K7-10A-01D-A17W-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/577f5df7-8d80-4f63-8f48-2369b19b6342

The open-access MAF lists 744 somatic variants for this specimen: 538 protein-altering or splice-affecting, 184 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 362, Silent 184, Frame Shift Del 111, Nonsense Mutation 26, Frame Shift Ins 21, Intron 14, Splice Site 8, In Frame Del 5, 3'UTR 4, Splice Region 4, RNA 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.5012del p.N1671Ifs*4 (on ENST00000272895 / NM_173076.3; = p.N1353Ifs*4 on NM_015657.3) | Frame Shift Del (DEL) | VAF 20/43 reads (47%) | catalogued as rs387906285, CD051281; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AGBL5 | c.826C>T p.R276W | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs879253769, COSV59938966; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AGXT | c.33dup p.K12Qfs*156 | Frame Shift Ins (INS) | VAF 34/74 reads (46%) | catalogued as rs180177201; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ARID1A | c.3826C>T p.R1276* | Nonsense Mutation (SNP) | VAF 26/57 reads (46%) | hotspot (GDC flag); catalogued as COSV61370466; called by muse, mutect2, varscan2
- FOXRED1 | c.1054C>T p.R352W | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs387907087, CM107966, COSV99702726; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2B | c.3325del p.R1109Efs*73 | Frame Shift Del (DEL) | VAF 25/62 reads (40%) | catalogued as rs1555729827, COSV55857298; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- KMT2D | c.4379del p.P1460Hfs*46 | Frame Shift Del (DEL) | VAF 8/37 reads (22%) | catalogued as rs1240601136; ClinVar: pathogenic; called by pindel, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 5/20 reads (25%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- PTEN | c.959T>A p.L320* | Nonsense Mutation (SNP) | VAF 9/30 reads (30%) | hotspot (GDC flag); catalogued as rs1114167667, CD110181, CM033671, CM1513166, CM992427, COSV64288766, COSV64288772, COSV64297208, COSV64305848; ClinVar: pathogenic; called by muse, varscan2
- PTEN | c.1008C>A p.Y336* | Nonsense Mutation (SNP) | VAF 13/24 reads (54%) | hotspot (GDC flag); catalogued as COSV64292408, COSV64294380, COSV64309461; called by muse, varscan2
- RAD50 | c.2801del p.N934Ifs*6 | Frame Shift Del (DEL) | VAF 20/45 reads (44%) | catalogued as rs748536322; ClinVar: pathogenic; called by mutect2, varscan2
- SALL4 | c.1954C>T p.Q652* | Nonsense Mutation (SNP) | VAF 13/27 reads (48%) | catalogued as rs74315424, CM022667, COSV99409404; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.7363C>T p.R2455W (on ENST00000614293; = p.R2425W on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs773689715, COSV99687420; called by muse, varscan2
- ABCA3 | c.4129C>T p.L1377F | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as COSV100068301; called by muse, mutect2, varscan2
- ABCA4 | c.6263G>T p.C2088F | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100933095; called by muse, mutect2, varscan2
- ABCA7 | c.4811C>T p.A1604V | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.348); catalogued as COSV99565562; called by muse, mutect2, varscan2
- ABCB7 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV99504200; called by muse, mutect2, varscan2
- ABCC12 | c.3775G>A p.V1259I | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV100252501, COSV60912968; called by muse, mutect2, varscan2
- ADAM23 | c.2340del p.K781Rfs*14 | Frame Shift Del (DEL) | VAF 27/53 reads (51%) | catalogued as rs767549806; called by mutect2, pindel, varscan2
- ADAMTS13 | c.3224G>A p.R1075H | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs138770906; called by muse, mutect2, varscan2
- ADAMTS5 | c.2273T>C p.I758T | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV99537405; called by muse, mutect2, varscan2
- ADCY8 | c.1751C>G p.T584S | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.417); catalogued as COSV53903809; called by muse, mutect2, varscan2
- ADGRA1 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.299); catalogued as COSV101658597; called by muse, mutect2, varscan2
- ADGRF2 | c.1891C>T p.R631* (on ENST00000296862 / NM_001368115.2; = p.R563* on NM_153839.7) | Nonsense Mutation (SNP) | VAF 19/37 reads (51%) | catalogued as rs555929821, COSV57288703; called by muse, mutect2, varscan2
- ADNP2 | c.971del p.P324Lfs*8 | Frame Shift Del (DEL) | VAF 23/56 reads (41%) | catalogued as rs772825390; called by mutect2, pindel, varscan2
- ADRA1A | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV99370582; called by muse, mutect2, varscan2
- AGL | c.1753A>G p.N585D | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99648991; called by muse, mutect2, varscan2
- ALDH1L1 | c.1399G>A p.A467T | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as rs369044554, COSV56411467, COSV56419494; called by muse, mutect2, varscan2
- ALG3 | c.241G>A p.V81I | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.47); catalogued as rs748076351, COSV56611253; called by muse, mutect2, varscan2
- AMER1 | c.1921C>T p.R641* | Nonsense Mutation (SNP) | VAF 68/148 reads (46%) | catalogued as COSV57654119; called by muse, mutect2, varscan2
- AMIGO3 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs774717692, COSV57540249; called by muse, mutect2, varscan2
- AMOTL2 | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51439181, COSV99998108; called by muse, mutect2, varscan2
- ANKRD13A | c.1435C>A p.H479N | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.573); catalogued as COSV99923920; called by muse, mutect2, varscan2
- ANXA11 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs749606073, COSV55416150; called by muse, mutect2, varscan2
- AOC2 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776084904, COSV99513584; called by muse, mutect2, varscan2
- AOPEP | c.2180G>A p.R727Q (on ENST00000375315 / NM_001193329.1; = p.R628Q on NM_032823.5) | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs963224133, COSV52987575; called by muse, mutect2, varscan2
- APMAP | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as rs201595930, COSV54177352; called by muse, mutect2, varscan2
- AQR | c.674T>G p.L225R | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99333702; called by muse, mutect2, varscan2
- ARAP3 | c.1937A>T p.E646V | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV99499551; called by muse, mutect2, varscan2
- ARHGAP17 | c.2440del p.Q814Nfs*23 (on ENST00000289968 / NM_001006634.3; = p.Q736Nfs*23 on NM_018054.6) | Frame Shift Del (DEL) | VAF 41/102 reads (40%) | catalogued as rs773922861; called by mutect2, pindel, varscan2
- ARHGAP9 | c.1014dup p.R339Afs*17 | Frame Shift Ins (INS) | VAF 11/40 reads (28%) | catalogued as rs771769575; called by mutect2, pindel, varscan2
- ARHGEF40 | c.4459dup p.H1487Pfs*28 | Frame Shift Ins (INS) | VAF 10/40 reads (25%) | catalogued as rs758492903; called by mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 10/27 reads (37%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ARID5A | c.310C>T p.L104= | Splice Region (SNP) | VAF 9/23 reads (39%) | catalogued as rs912789080, COSV100673566; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.626del p.N209Ifs*9 | Frame Shift Del (DEL) | VAF 26/68 reads (38%) | catalogued as rs1295666772; called by mutect2, pindel, varscan2
- ASIC2 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as rs565904010, COSV63314653; called by muse, mutect2, varscan2
- ATAD2 | c.354del p.E119Kfs*8 | Frame Shift Del (DEL) | VAF 14/34 reads (41%) | catalogued as rs746676748; called by mutect2, varscan2
- ATP9B | c.1240C>T p.L414F | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as COSV100303317; called by muse, mutect2, varscan2
- B4GALNT3 | c.2023C>T p.R675* | Nonsense Mutation (SNP) | VAF 13/19 reads (68%) | catalogued as rs199814733; called by muse, varscan2
- B4GALNT4 | c.2972del p.G991Vfs*71 | Frame Shift Del (DEL) | VAF 11/34 reads (32%) | catalogued as rs35951843; called by mutect2, pindel, varscan2
- BACE2 | c.305del p.P102Rfs*25 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | catalogued as rs771098505; called by mutect2, pindel
- BAHCC1 | c.1691C>T p.A564V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.049); catalogued as rs781837379, COSV100311463; called by muse, mutect2
- BAZ2A | c.4460C>T p.P1487L | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV51631872, COSV99465458; called by muse, mutect2, varscan2
- BAZ2A | c.1036A>G p.N346D | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.42); PolyPhen benign (0.055); catalogued as COSV99465462; called by muse, mutect2, varscan2
- BCL11A | c.2369G>A p.S790N (on ENST00000335712 / NM_001365609.1; = p.S824N on NM_022893.4) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.792); catalogued as COSV59627622; called by muse, mutect2
- BLVRA | c.673C>T p.R225* | Nonsense Mutation (SNP) | VAF 17/35 reads (49%) | catalogued as rs754440828, COSV55516258; called by muse, mutect2
- BMS1 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs768970108, COSV100996649; called by muse, mutect2, varscan2
- BRINP1 | c.2105G>A p.R702Q | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV56297833; called by muse, mutect2, varscan2
- BTAF1 | c.1562G>A p.R521H | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99795191; called by muse, mutect2, varscan2
- BTAF1 | c.4225A>G p.I1409V | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99795192; called by muse, mutect2, varscan2
- BTBD11 | c.1357del p.L453Cfs*53 | Frame Shift Del (DEL) | VAF 13/41 reads (32%) | catalogued as rs777776928; called by mutect2, pindel, varscan2
- BTBD2 | c.869C>T p.S290F | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1032991552, COSV99724685; called by muse, mutect2, varscan2
- BUB1 | c.3208C>T p.R1070C | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as rs191292475, COSV57063201; called by muse, mutect2, varscan2
- BZW1 | c.648+3_648+6del p.X216_splice | Splice Site (DEL) | VAF 14/36 reads (39%) | catalogued as rs764044949; called by pindel, varscan2
- C15orf39 | c.2662G>A p.A888T | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.975); catalogued as rs969404764, COSV100641282; called by muse, mutect2, varscan2
- C19orf53 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV99237379; called by muse, mutect2, varscan2
- C20orf85 | c.269del p.P90Qfs*19 | Frame Shift Del (DEL) | VAF 16/36 reads (44%) | catalogued as rs777635732, COSV100959338, COSV64519981; called by mutect2, varscan2
- C9orf135 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as rs976802265, COSV101019812; called by muse, mutect2, varscan2
- CACNA1E | c.4102G>A p.V1368I | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.693); catalogued as rs574530214, COSV62402477; called by muse, mutect2, varscan2
- CARMIL3 | c.2278T>C p.S760P | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as COSV100549511; called by mutect2, varscan2
- CATSPER2 | c.610G>A p.V204M | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.16); catalogued as COSV100390675; called by muse, mutect2, varscan2
- CBX1 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99848079; called by muse, mutect2, varscan2
- CC2D1A | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780812392, COSV100528742, COSV58785444; called by muse, mutect2, varscan2
- CCDC148 | c.1022C>T p.T341I | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99320137; called by muse, mutect2, varscan2
- CCDC191 | c.1499C>T p.T500I | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV99878113; called by muse, mutect2, varscan2
- CCDC88C | c.522G>A p.W174* | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | catalogued as COSV101105493; called by muse, mutect2, varscan2
- CCM2 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as rs762020337, COSV51847362; called by muse, mutect2
- CD180 | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.25); catalogued as rs140099362; called by muse, mutect2, varscan2
- CD300LG | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as rs146042431; called by muse, mutect2, varscan2
- CDH10 | c.1577del p.F526Sfs*3 | Frame Shift Del (DEL) | VAF 14/26 reads (54%) | catalogued as rs1209448007; called by mutect2, varscan2
- CDH19 | c.1250A>C p.N417T | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.263); catalogued as COSV50976187; called by muse, mutect2, varscan2
- CDH23 | c.8306C>T p.A2769V | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.535); catalogued as COSV99820235; called by muse, mutect2, varscan2
- CDIPT | c.524G>A p.G175D | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.242); catalogued as COSV99570160; called by muse, mutect2, varscan2
- CDKN1A | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.419); catalogued as COSV55189837; called by muse, mutect2, varscan2
- CENATAC | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as COSV100548697; called by muse, mutect2, varscan2
- CENPB | c.1645G>A p.A549T | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV60146168; called by muse, mutect2, varscan2
- CEP350 | c.2639C>A p.P880H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100854479, COSV62599539; called by muse, mutect2, varscan2
- CEP350 | c.8137G>T p.E2713* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as COSV100854480; called by muse, mutect2, varscan2
- CHAF1A | c.2182C>T p.R728W | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.479); catalogued as rs113859101, COSV100011054; called by muse, mutect2, varscan2
- CHD4 | c.3163C>T p.R1055C (on ENST00000357008 / NM_001363606.2; = p.R1068C on NM_001273.5) | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58894255; called by muse, mutect2, varscan2
- CHL1 | c.2257C>T p.P753S (on ENST00000397491 / NM_001253387.1; = p.P769S on NM_006614.4) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.355); catalogued as rs1306391833, COSV99850781; called by muse, mutect2, varscan2
- CHM | c.94C>T p.R32W | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as rs1169868760, COSV62566124; called by muse, mutect2, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | catalogued as rs751548647; called by mutect2, varscan2
- CHRNA6 | c.140A>G p.Q47R | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV99373176; called by muse, mutect2, varscan2
- CHST12 | c.464G>A p.S155N | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV99324410; called by muse, mutect2, varscan2
- CIDEB | c.639G>T p.K213N | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV99350624, COSV99351108; called by muse, mutect2, varscan2
- CIP2A | c.1060G>A p.G354R | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as rs753914865, COSV55419568, COSV99842596; called by muse, mutect2, varscan2
- CLUH | c.1873G>A p.A625T (on ENST00000435359; = p.A663T on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.892); catalogued as rs747365123, COSV70928181; called by muse, mutect2, varscan2
- CMTM5 | c.377del p.P126Rfs*55 | Frame Shift Del (DEL) | VAF 11/30 reads (37%) | catalogued as rs751921758; called by mutect2, pindel, varscan2
- CNR1 | c.1336G>A p.A446T | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0.037); catalogued as rs772492894, COSV62989613; called by muse, mutect2, varscan2
- CNTLN | c.3922del p.M1308* | Frame Shift Del (DEL) | VAF 12/35 reads (34%) | catalogued as rs761011518, COSV99078405; called by mutect2, pindel, varscan2
- CPSF4 | c.289T>C p.Y97H | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV99462256; called by muse, mutect2, varscan2
- CRIP2 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs374234792; called by muse, mutect2, varscan2
- CTCF | c.972C>A p.C324* | Nonsense Mutation (SNP) | VAF 23/70 reads (33%) | catalogued as COSV99864985; called by muse, mutect2, varscan2
- CTCF | c.1598G>A p.R533H | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50464414, COSV99864989; called by muse, mutect2, varscan2
- DAPK1 | c.1063G>A p.D355N | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.994); catalogued as COSV100801562; called by muse, mutect2, varscan2
- DCAF10 | c.667C>T p.R223W | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1327130792, COSV54291547; called by muse, mutect2, varscan2
- DCAF12L2 | c.942C>G p.Y314* | Nonsense Mutation (SNP) | VAF 16/48 reads (33%) | catalogued as COSV100758541; called by muse, mutect2, varscan2
- DCAF15 | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs748698814, COSV99585975; called by muse, varscan2
- DCAF4L2 | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as COSV60480325; called by muse, mutect2, varscan2
- DCBLD2 | c.2055G>A p.M685I | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99504724; called by muse, mutect2, varscan2
- DEPDC5 | c.2018C>T p.A673V (on ENST00000400246; = p.A742V on NM_014662.5) | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56712245; called by muse, mutect2, varscan2
- DHX34 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs200529916, COSV60898775; called by mutect2, varscan2
- DHX40 | c.2321C>T p.T774I | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV99232871; called by muse, mutect2, varscan2
- DIDO1 | c.6076C>A p.L2026M | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99825433; called by muse, mutect2
- DIS3L2 | c.1205-2A>T p.X402_splice | Splice Site (SNP) | VAF 31/86 reads (36%) | catalogued as COSV99805951; called by muse, mutect2, varscan2
- DKK2 | c.564C>A p.D188E | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99568489; called by muse, mutect2, varscan2
- DNA2 | c.2335del p.S779Hfs*6 | Frame Shift Del (DEL) | VAF 26/48 reads (54%) | catalogued as rs745893364; called by mutect2, varscan2
- DNAH11 | c.6800T>A p.I2267N | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100178593; called by muse, mutect2, varscan2
- DNAJA4 | c.583G>A p.E195K (on ENST00000343789; = p.E224K on NM_018602.3) | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746550055, COSV59426607; called by muse, mutect2, varscan2
- DNAJB13 | c.97C>G p.P33A | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs1349327945, COSV100334483; called by muse, mutect2
- DNM1 | c.689-1G>T p.X230_splice | Splice Site (SNP) | VAF 17/35 reads (49%) | catalogued as COSV100359775; called by muse, mutect2
- DNTTIP1 | c.251C>G p.T84S | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV99714508; called by muse, mutect2, varscan2
- DOCK6 | c.1508C>T p.A503V | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.033); catalogued as COSV99370921; called by muse, mutect2
- DSCAML1 | c.952C>T p.R318C (on ENST00000321322; = p.R258C on NM_020693.4) | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58384642; called by muse, mutect2, varscan2
- DST | c.17648C>A p.P5883H (on ENST00000361203 / NM_001374722.1; = p.P3580H on NM_015548.5) | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99754169; called by muse, mutect2, varscan2
- E2F1 | c.1303del p.L435Wfs*58 | Frame Shift Del (DEL) | VAF 16/30 reads (53%) | catalogued as rs1409099723, COSV55776265; called by mutect2, varscan2
- EEF2 | c.1225C>T p.R409W | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58580116; called by muse, mutect2, varscan2
- EHMT2 | c.3137C>T p.A1046V | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.098); catalogued as COSV99998845; called by muse, mutect2, varscan2
- EML3 | c.1343G>A p.R448Q | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV53903568; called by muse, mutect2, varscan2
- EPPK1 | c.101C>T p.T34M | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.402); catalogued as rs782642241, COSV73261737; called by muse, mutect2, varscan2
- EPRS1 | c.3632C>T p.T1211M | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756764132, COSV65098141; called by muse, mutect2, varscan2
- ERCC2 | c.1195C>A p.L399I | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.139); catalogued as COSV99676205; called by muse, mutect2, varscan2
- ERICH6 | c.1778A>G p.D593G | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99901547; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 56/60 reads (93%) | catalogued as rs775950025; called by mutect2, varscan2
- EVI2A | c.674_676del p.E225del | In Frame Del (DEL) | VAF 40/116 reads (34%) | catalogued as rs1180324399; called by pindel, varscan2
- EXOC7 | c.1055-3del | Splice Region (DEL) | VAF 34/66 reads (52%) | catalogued as rs767353873; called by mutect2, varscan2
- EXT1 | c.1780G>A p.A594T | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.64); PolyPhen benign (0.277); catalogued as rs1388996809, COSV65484872; called by muse, mutect2, varscan2
- F2R | c.523T>C p.C175R | Missense Mutation (SNP) | VAF 48/88 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100058417; called by muse, mutect2, varscan2
- FADS3 | c.627C>A p.G209= | Splice Region (SNP) | VAF 14/34 reads (41%) | catalogued as COSV99605229; called by muse, mutect2, varscan2
- FAM124B | c.382del p.V128* | Frame Shift Del (DEL) | VAF 9/20 reads (45%) | catalogued as COSV66271694; called by mutect2, varscan2
- FAM161B | c.1607del p.K536Rfs*25 (on ENST00000651776; = p.K473Rfs*25 on NM_152445.3) | Frame Shift Del (DEL) | VAF 16/37 reads (43%) | catalogued as COSV54105123; called by mutect2, pindel, varscan2
- FAM171B | c.2449C>T p.R817* | Nonsense Mutation (SNP) | VAF 21/41 reads (51%) | catalogued as rs757771338, COSV59005035; called by muse, mutect2, varscan2
- FAM209B | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.125); catalogued as COSV100990945; called by mutect2, varscan2
- FAM47B | c.1932_1934del p.E644del | In Frame Del (DEL) | VAF 25/65 reads (38%) | catalogued as rs1292060875; called by pindel, varscan2
- FAM47C | c.1085G>A p.R362H | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs149671724, COSV63725620; called by muse, mutect2, varscan2
- FAM98C | c.506C>A p.P169H | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.753); catalogued as COSV99384937; called by muse, mutect2, varscan2
- FATE1 | c.420G>T p.Q140H | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as COSV100948133; called by muse, mutect2, varscan2
- FBLL1 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs748839022, COSV100606150; called by muse, mutect2, varscan2
- FBXO11 | c.1306A>G p.I436V (on ENST00000403359 / NM_001190274.2; = p.I352V on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.71); PolyPhen benign (0.391); catalogued as COSV100319342; called by muse, mutect2, varscan2
- FBXW12 | c.350C>T p.S117L | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.748); catalogued as COSV56483346, COSV99601566; called by muse, mutect2, varscan2
- FGF10 | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99240407; called by muse, mutect2, varscan2
- FLRT2 | c.1750C>T p.R584W | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1248212249, COSV58136841; called by muse, mutect2, varscan2
- FMN1 | c.2558C>T p.A853V (on ENST00000616417 / NM_001277313.2; = p.A630V on NM_001103184.4) | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV100568379; called by muse, mutect2
- FSTL4 | c.1195C>T p.H399Y | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.801); catalogued as COSV99532152; called by muse, mutect2, varscan2
- FZD4 | c.829C>T p.R277W | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs768216168, COSV101536039; called by mutect2, varscan2
- GAB1 | c.596C>T p.T199M | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as rs780926544, COSV99528180; called by muse, mutect2, varscan2
- GABRB1 | c.1231C>T p.R411C | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV54986839, COSV54988273, COSV55000495; called by muse, mutect2, varscan2
- GALNT11 | c.1202G>A p.R401Q | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746458339, COSV57424900; called by muse, mutect2, varscan2
- GARRE1 | c.625G>A p.G209S | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as rs1329156111, COSV100209272; called by muse, mutect2, varscan2
- GBP5 | c.103A>G p.T35A | Missense Mutation (SNP) | VAF 55/143 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as COSV100600030; called by muse, mutect2, varscan2
- GJA4 | c.322C>T p.Q108* | Nonsense Mutation (SNP) | VAF 14/27 reads (52%) | catalogued as COSV100654664; called by muse, mutect2, varscan2
- GLB1L | c.395del p.G132Vfs*14 | Frame Shift Del (DEL) | VAF 11/31 reads (35%) | catalogued as rs780866249; called by pindel, varscan2
- GLIS1 | c.1517del p.P506Rfs*144 | Frame Shift Del (DEL) | VAF 5/37 reads (14%) | catalogued as COSV56545214, COSV56551931; called by mutect2, pindel, varscan2
- GNA14 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as COSV100502793; called by muse, mutect2, varscan2
- GNAL | c.623T>C p.M208T (on ENST00000269162 / NM_001142339.3; = p.M285T on NM_182978.4) | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99303328; called by muse, mutect2, varscan2
- GOLGB1 | c.9680G>A p.R3227H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs114624117, COSV100100556; called by mutect2, varscan2
- GPR151 | c.226_227del p.L76Dfs*8 | Frame Shift Del (DEL) | VAF 14/41 reads (34%) | catalogued as rs757941978; called by mutect2, pindel, varscan2
- GPRC5A | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs748582997, COSV99185547; called by muse, mutect2, varscan2
- GRIP2 | c.2841G>T p.E947D (on ENST00000619221; = p.E850D on NM_001080423.4) | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as COSV56125428; called by muse, mutect2, varscan2
- GRK6 | c.241G>A p.V81I | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747788540, COSV100586867; called by muse, mutect2, varscan2
- GRM8 | c.2309C>T p.T770M | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs147639816, COSV100282011; called by muse, mutect2, varscan2
- GSDMC | c.229G>A p.V77M | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.897); catalogued as COSV99415838; called by muse, mutect2, varscan2
- HAS2 | c.167A>G p.H56R | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100391346, COSV100391654; called by muse, mutect2, varscan2
- HBM | c.392G>A p.G131D | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.46); PolyPhen benign (0.119); catalogued as COSV100720781; called by muse, mutect2, varscan2
- HELB | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV56076466, COSV99921678; called by muse, mutect2, varscan2
- HHATL | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs770759404, COSV60042697; called by muse, mutect2, varscan2
- HINFP | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1046279925, COSV100640834; called by muse, mutect2, varscan2
- HK2 | c.781T>C p.W261R | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99308873; called by muse, mutect2, varscan2
- HNMT | c.358T>C p.S120P | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV99698828; called by muse, mutect2, varscan2
- HR | c.1371G>T p.K457N | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.563); catalogued as COSV100455760; called by muse, mutect2, varscan2
- HRH3 | c.1171G>A p.D391N | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.67); PolyPhen benign (0.077); catalogued as COSV100420509; called by muse, mutect2, varscan2
- HSF1 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.488); catalogued as rs781953503, COSV60047507; called by muse, mutect2, varscan2
- HSH2D | c.581C>G p.S194C | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV53738329, COSV99507103, COSV99507180; called by muse, mutect2, varscan2
- HTR7 | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0.068); catalogued as rs1200616724, COSV99519321; called by muse, mutect2, varscan2
- HTRA4 | c.1382G>A p.R461Q | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769279631, COSV56761082; called by muse, mutect2, varscan2
- HYDIN | c.6818T>C p.M2273T | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs751359163, COSV99992515; called by muse, mutect2, varscan2
- ICA1 | c.611del p.N204Tfs*5 | Frame Shift Del (DEL) | VAF 28/77 reads (36%) | catalogued as rs747841314; called by mutect2, varscan2
- IFIT2 | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as rs775027680, COSV51078970, COSV99260146; called by muse, mutect2, varscan2
- IGF2BP1 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 49/87 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.149); catalogued as COSV51730320, COSV99288519; called by muse, mutect2, varscan2
- IGFBP4 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV99511171; called by muse, mutect2, varscan2
- IGSF9B | c.439dup p.Q147Pfs*10 | Frame Shift Ins (INS) | VAF 15/44 reads (34%) | catalogued as rs748943611; called by mutect2, varscan2
- IRF7 | c.1100C>T p.A367V (on ENST00000397566; = p.A354V on NM_001572.5) | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.6); catalogued as rs1472777001, COSV52756239; called by mutect2, varscan2
- IRS1 | c.3151G>A p.A1051T | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.43); PolyPhen benign (0.014); catalogued as COSV100524335; called by muse, mutect2, varscan2
- ISLR | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.876); catalogued as rs1233443000, COSV51433274; called by muse, mutect2, varscan2
- ITGA11 | c.846G>T p.K282N | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.474); catalogued as COSV100241317; called by muse, mutect2, varscan2
- KATNB1 | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as rs144107393; called by muse, mutect2, varscan2
- KCNG3 | c.673G>C p.E225Q | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100044920; called by muse, mutect2, varscan2
- KCNK9 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); catalogued as rs1222560554, COSV100270171; called by muse, mutect2
- KCNN4 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs1283088843, COSV53455405, COSV53455663; called by muse, mutect2, varscan2
- KDM5C | c.3233C>T p.A1078V | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.9); catalogued as COSV100949015; called by muse, mutect2, varscan2
- KDM6B | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.065); catalogued as COSV99641107; called by muse, mutect2, varscan2
- KIAA0513 | c.936del p.F312Lfs*32 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | catalogued as rs1567545747; called by mutect2, pindel, varscan2
- KIAA0895 | c.584G>C p.G195A (on ENST00000297063 / NM_001100425.2; = p.G144A on NM_015314.3) | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as COSV99766730; called by muse, mutect2
- KIF27 | c.3097C>T p.R1033C | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs765041527, COSV99926897; called by muse, mutect2, varscan2
- KLF3 | c.677del p.P226Rfs*52 | Frame Shift Del (DEL) | VAF 11/26 reads (42%) | catalogued as COSV54711577; called by mutect2, pindel, varscan2
- KLHDC8B | c.48del p.M17Cfs*59 | Frame Shift Del (DEL) | VAF 20/57 reads (35%) | catalogued as rs756907493; called by mutect2, pindel, varscan2
- KLHL31 | c.312del p.D105Tfs*15 | Frame Shift Del (DEL) | VAF 11/36 reads (31%) | catalogued as rs1227078726; called by mutect2, pindel, varscan2
- KMT2C | c.6196C>T p.R2066* | Nonsense Mutation (SNP) | VAF 10/27 reads (37%) | catalogued as rs1211949081, COSV51437028; called by muse, mutect2, varscan2
- KMT2C | c.2378C>T p.S793L | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs537871923, COSV51508614; called by muse, mutect2, varscan2
- KMT2D | c.4361C>T p.T1454I | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99979950; called by muse, varscan2
- KRBA1 | c.1663G>T p.G555W | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV99752519; called by muse, varscan2
- KRT75 | c.898G>A p.G300S | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs368136976; called by muse, mutect2, varscan2
- KRTAP10-4 | c.619T>G p.S207A | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.07); catalogued as COSV100552838; called by muse, mutect2, varscan2
- KSR2 | c.1364C>T p.P455L | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV100194712; called by muse, mutect2, varscan2
- LDLRAP1 | c.604del p.S202Pfs*2 | Frame Shift Del (DEL) | VAF 16/45 reads (36%) | catalogued as COSV65473126, COSV65473260; called by mutect2, pindel, varscan2
- LFNG | c.700A>G p.I234V (on ENST00000222725 / NM_001040167.2; = p.I105V on NM_002304.2) | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.456); catalogued as rs1313106586, COSV99761741; called by muse, mutect2, varscan2
- LIMD1 | c.151A>G p.K51E | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1289954459, COSV99836877; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 32/60 reads (53%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LPAR2 | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.772); catalogued as rs868311564, COSV101345489; called by muse, mutect2
- LRPPRC | c.1655T>G p.M552R | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0.024); catalogued as COSV99580377; called by muse, mutect2, varscan2
- LRRC74A | c.112C>T p.R38* | Nonsense Mutation (SNP) | VAF 13/29 reads (45%) | catalogued as rs200189415, COSV99372215; called by muse, mutect2, varscan2
- LRRC8D | c.1213A>G p.S405G | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV100487178; called by muse, mutect2, varscan2
- LRRIQ3 | c.414del p.G139Dfs*20 | Frame Shift Del (DEL) | VAF 27/60 reads (45%) | catalogued as rs749244073; called by mutect2, pindel, varscan2
- LSS | c.1609G>A p.V537M | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs769378489, COSV62700980; called by muse, mutect2, varscan2
- MAP3K4 | c.3890T>C p.I1297T | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV100815237; called by muse, mutect2, varscan2
- MAP3K5 | c.3307C>T p.R1103* | Nonsense Mutation (SNP) | VAF 14/27 reads (52%) | catalogued as COSV100752677; called by muse, mutect2, varscan2
- MAP3K7 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs139832891; called by muse, mutect2, varscan2
- MAP4K1 | c.1838-1G>A p.X613_splice | Splice Site (SNP) | VAF 10/30 reads (33%) | catalogued as COSV101204189; called by muse, mutect2, varscan2
- MATN4 | c.1065C>A p.S355R (on ENST00000372754; = p.S314R on NM_003833.4) | Missense Mutation (SNP) | VAF 12/30 reads (40%) | PolyPhen possibly damaging (0.888); catalogued as COSV100636965; called by muse, mutect2, varscan2
- MBD6 | c.2345dup p.A783Sfs*10 | Frame Shift Ins (INS) | VAF 11/32 reads (34%) | catalogued as rs746267361; called by mutect2, varscan2
- MCF2L2 | c.1858del p.R620Afs*16 | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | catalogued as COSV100193332; called by mutect2, varscan2
- MED25 | c.602dup p.A202Gfs*197 | Frame Shift Ins (INS) | VAF 14/38 reads (37%) | catalogued as rs748546983; ClinVar: uncertain significance; called by mutect2, varscan2
- MFSD2A | c.358T>C p.S120P (on ENST00000372809 / NM_001136493.3; = p.S107P on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100861659; called by muse, mutect2, varscan2
- MIS18BP1 | c.2068del p.S690Vfs*10 | Frame Shift Del (DEL) | VAF 18/41 reads (44%) | catalogued as rs750307488; called by mutect2, varscan2
- MKI67 | c.698del p.N233Mfs*12 | Frame Shift Del (DEL) | VAF 9/20 reads (45%) | catalogued as rs749903408; called by mutect2, varscan2
- MKLN1 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100759777; called by muse, mutect2, varscan2
- MMP24 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99863762; called by muse, mutect2, varscan2
- MMP9 | c.1637G>A p.R546K | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100812386; called by muse, mutect2, varscan2
- MOB1B | c.567del p.F189Lfs*19 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as rs778232663; called by mutect2, varscan2
- MORC1 | c.2641del p.I881* | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs757379917; called by mutect2, varscan2
- MRPL43 | c.436C>T p.R146* | Nonsense Mutation (SNP) | VAF 27/53 reads (51%) | catalogued as COSV99272249; called by muse, mutect2, varscan2
- MRPS5 | c.548A>G p.K183R | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99720779; called by muse, mutect2, varscan2
- MS4A3 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV99614662; called by muse, mutect2, varscan2
- MSH5 | c.1970A>G p.K657R | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.4); PolyPhen benign (0.046); catalogued as COSV100991803; called by muse, mutect2, varscan2
- MTA1 | c.1296G>A p.M432I | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as COSV100495071; called by muse, mutect2, varscan2
- MTBP | c.344C>T p.T115M | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs183822788, COSV59966774; called by muse, mutect2, varscan2
- MTR | c.475G>A p.V159M | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100855946; called by muse, mutect2, varscan2
- MTUS2 | c.1902G>A p.M634I | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV101462163; called by muse, mutect2, varscan2
- MUC17 | c.8468C>T p.A2823V | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV100072688; called by muse, mutect2, varscan2
- MUC6 | c.7069_7071del p.E2357del | In Frame Del (DEL) | VAF 16/61 reads (26%) | catalogued as rs766760246; called by pindel, varscan2
- MYCBPAP | c.1739C>T p.A580V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.415); catalogued as COSV100087986; called by muse, mutect2, varscan2
- MYH14 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as rs138001307; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH15 | c.2462A>G p.D821G | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.721); catalogued as COSV99842911; called by muse, mutect2, varscan2
- MYH3 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs202142101; called by muse, mutect2, varscan2
- NACA | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV63267767; called by muse, mutect2, varscan2
- NAGS | c.31C>T p.R11W | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs760911430, COSV99517840; called by muse, mutect2, varscan2
- NAV1 | c.1085G>T p.S362I | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.23); catalogued as COSV99818584; called by muse, mutect2, varscan2
- NBEAL2 | c.1197G>T p.K399N | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52755773; called by muse, mutect2, varscan2
- NCOA1 | c.2381C>A p.P794H | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV99945737; called by muse, mutect2, varscan2
- NDRG1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 35/72 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.437); catalogued as COSV100105876; called by muse, mutect2, varscan2
- NELFA | c.1396G>A p.E466K (on ENST00000542778; = p.E455K on NM_005663.5) | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752273389, COSV100372961; called by muse, mutect2, varscan2
- NEMF | c.2966C>A p.P989H | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); catalogued as COSV100026944; called by muse, mutect2, varscan2
- NEO1 | c.1823G>A p.R608Q | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs769566233, COSV56078993; called by muse, mutect2, varscan2
- NF2 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as rs1427589827, COSV58532932; called by muse, mutect2, varscan2
- NFKB2 | c.2486C>T p.A829V | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV99192409; called by muse, mutect2, varscan2
- NFU1 | c.545G>A p.R182Q (on ENST00000410022 / NM_001002755.4; = p.R158Q on NM_015700.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1281276965, CS118326, COSV58005896; called by muse, mutect2, varscan2
- NKTR | c.2575del p.R859Efs*3 | Frame Shift Del (DEL) | VAF 6/11 reads (55%) | catalogued as rs757068777; called by mutect2, varscan2
- NOL7 | c.714dup p.Q239Tfs*7 | Frame Shift Ins (INS) | VAF 17/44 reads (39%) | catalogued as rs544905440; called by mutect2, varscan2
- NOTCH1 | c.4835G>A p.G1612D | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1223921509, COSV99486881; called by muse, mutect2, varscan2
- NOXO1 | c.98G>A p.G33D | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.91); PolyPhen benign (0.009); catalogued as COSV99937020; called by muse, mutect2, varscan2
- NPDC1 | c.445G>A p.G149R | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.929); catalogued as rs751469138, COSV100064004; called by muse, mutect2, varscan2
- NPHS1 | c.1511A>T p.K504I | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.16); catalogued as COSV100799739; called by muse, mutect2, varscan2
- NPY2R | c.796del p.T266Pfs*35 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | catalogued as rs758758894; called by mutect2, pindel, varscan2
- NT5M | c.622del p.R208Afs*34 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | catalogued as rs754390000; called by mutect2, pindel, varscan2
- NTRK3 | c.1849T>C p.F617L | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100712616; called by muse, mutect2, varscan2
- NUDT10 | c.403G>A p.V135M | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1557312396, COSV100726797; called by muse, mutect2, varscan2
- NUDT22 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs764713316, COSV99655768; called by muse, mutect2, varscan2
- NUP133 | c.2774T>C p.L925S | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99772806; called by muse, mutect2, varscan2
- NUP210L | c.2072del p.L691Wfs*3 | Frame Shift Del (DEL) | VAF 9/19 reads (47%) | catalogued as rs760869296; called by mutect2, varscan2
- NUS1 | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.766); catalogued as COSV100874917; called by muse, mutect2, varscan2
- OLFML2A | c.1711C>T p.R571W | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs369965570, COSV56585775, COSV99992653; called by muse, mutect2, varscan2
- OR10A4 | c.70C>T p.L24F | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV65842046; called by muse, mutect2
- OR1S2 | c.361G>A p.V121I | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT tolerated (0.25); PolyPhen benign (0.037); catalogued as COSV100224101; called by muse, mutect2, varscan2
- OR2A1 | c.367G>A p.V123M | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.491); catalogued as rs752118797, COSV101283371; called by muse, mutect2, varscan2
- OR2C3 | c.670C>T p.R224W | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs1195741075, COSV63574692, COSV63576737; called by muse, mutect2, varscan2
- OR5P2 | c.247G>A p.V83M | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.063); catalogued as COSV100271283, COSV61489968; called by muse, mutect2, varscan2
- OR6M1 | c.180C>A p.F60L | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100484048, COSV58433624; called by muse, mutect2, varscan2
- PCDH8 | c.2983C>T p.R995W | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100131446; called by muse, mutect2, varscan2
- PCDHA12 | c.1768G>A p.V590M | Missense Mutation (SNP) | VAF 76/148 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.529); catalogued as rs1481558429, COSV100249844, COSV56481676; called by muse, mutect2, varscan2
- PCDHA8 | c.1931G>T p.R644L | Missense Mutation (SNP) | VAF 45/78 reads (58%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.088); catalogued as COSV100969362; called by muse, mutect2, varscan2
- PCDHB12 | c.2053T>A p.S685T | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as rs1554287095, COSV99507110; called by muse, mutect2, varscan2
- PCDHGA4 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.08); catalogued as rs758635124, COSV99528835, COSV99535460; called by muse, mutect2, varscan2
- PCDHGC3 | c.2050del p.R684Gfs*15 | Frame Shift Del (DEL) | VAF 13/28 reads (46%) | catalogued as rs764598056; called by mutect2, pindel, varscan2
- PCGF6 | c.717del p.V240Sfs*2 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | catalogued as rs35956583; called by mutect2, pindel, varscan2
- PCNX1 | c.3958T>C p.W1320R | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99455152; called by muse, mutect2, varscan2
- PCYT2 | c.338G>A p.G113D | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100155471; called by muse, mutect2, varscan2
- PEG3 | c.1802A>T p.E601V | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.72); catalogued as COSV99688373; called by muse, mutect2, varscan2
- PER1 | c.1408G>A p.V470M | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1276989740, COSV100424441; called by muse, mutect2, varscan2
- PFKP | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.803); catalogued as COSV101126815, COSV101127136; called by muse, mutect2, varscan2
- PIK3C2B | c.4303G>A p.G1435S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as rs140065111; called by muse, mutect2, varscan2
- PITPNM3 | c.782G>A p.C261Y | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV52600026, COSV99338216; called by muse, mutect2, varscan2
- PKMYT1 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99234005; called by muse, mutect2, varscan2
- PLEKHA7 | c.1448del p.G483Afs*23 | Frame Shift Del (DEL) | VAF 28/62 reads (45%) | catalogued as COSV63050791; called by mutect2, pindel, varscan2
- PLEKHG6 | c.1456G>A p.A486T | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as rs184437633, COSV99164159; called by muse, mutect2, varscan2
- PLEKHH3 | c.2054T>C p.L685S | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as COSV99257478; called by muse, mutect2, varscan2
- PLXNA4 | c.649G>A p.V217I | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.625); catalogued as rs762527511, COSV58161351; called by muse, mutect2, varscan2
- PLXNB1 | c.2837G>A p.G946D | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0.021); catalogued as COSV99602654; called by muse, mutect2, varscan2
- PLXNB1 | c.1529G>A p.R510H | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs759375530, COSV56488700; called by muse, mutect2, varscan2
- POLE | c.6497A>G p.D2166G | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100266013; called by muse, mutect2, varscan2
- POLE | c.1187A>G p.E396G | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.959); catalogued as COSV57679544; called by muse, mutect2, varscan2
- PPP4R3B | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.985); catalogued as rs770258878, COSV55404083; called by muse, mutect2, varscan2
- PRAMEF1 | c.1205G>A p.S402N | Missense Mutation (SNP) | VAF 86/241 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.248); catalogued as COSV100179625; called by muse, mutect2, varscan2
- PRAMEF20 | c.1154G>A p.R385H | Missense Mutation (SNP) | VAF 54/212 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.703); catalogued as rs965592462; called by muse, mutect2, varscan2
- PRKDC | c.496del p.I166Yfs*6 | Frame Shift Del (DEL) | VAF 20/46 reads (43%) | catalogued as rs537061158; called by mutect2, varscan2
- PRODH2 | c.629C>T p.A210V (on ENST00000301175; = p.A134V on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs35841154, COSV99995277; called by muse, mutect2, varscan2
- PRPF40B | c.99del p.M34Cfs*29 (on ENST00000380281; = p.M28Cfs*29 on NM_012272.3) | Frame Shift Del (DEL) | VAF 15/33 reads (45%) | catalogued as COSV56058435; called by mutect2, pindel, varscan2
- PRRG1 | c.401del p.P134Hfs*19 | Frame Shift Del (DEL) | VAF 22/52 reads (42%) | catalogued as rs781858060; called by mutect2, varscan2
- PRTFDC1 | c.552C>T p.D184= | Splice Region (SNP) | VAF 13/21 reads (62%) | catalogued as rs774956717, COSV100196860; called by muse, varscan2
- PSD | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs773796171, COSV50046501; called by muse, mutect2, varscan2
- PSD3 | c.1573C>A p.L525M | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV100495808; called by muse, mutect2, varscan2
- PSKH1 | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99344592; called by muse, mutect2, varscan2
- PSMA7 | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.19); PolyPhen benign (0.072); catalogued as COSV53379854; called by muse, mutect2, varscan2
- PTDSS2 | c.1331G>A p.R444Q | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs370331186; called by muse, mutect2, varscan2
- PTEN | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100909680, COSV64293534, COSV64307061; called by muse, mutect2, varscan2
- PWWP2A | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs758270619, COSV61048046; called by muse, mutect2, varscan2
- QKI | c.401dup p.E135Gfs*5 | Frame Shift Ins (INS) | VAF 12/34 reads (35%) | catalogued as rs755727862; called by mutect2, varscan2
- RAB42 | c.51G>C p.K17N | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100866075; called by muse, mutect2, varscan2
- RALGAPB | c.2407C>T p.R803W | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs909701420, COSV99485046; called by muse, mutect2, varscan2
- RASA1 | c.566C>T p.T189M | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.051); catalogued as rs986802785, COSV99169726; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- REV3L | c.7292G>A p.R2431Q | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62616623, COSV62625435; called by muse, mutect2, varscan2
- RIC1 | c.2576A>G p.H859R | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99317058; called by muse, mutect2, varscan2
- RIMKLA | c.790A>G p.M264V | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.029); catalogued as COSV101290561; called by muse, mutect2, varscan2
- RIMKLB | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as COSV55236273; called by muse, mutect2, varscan2
- RNF25 | c.1195C>T p.Q399* | Nonsense Mutation (SNP) | VAF 24/62 reads (39%) | catalogued as COSV99828916; called by muse, mutect2, varscan2
- RNF31 | c.1847G>A p.R616H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.306); catalogued as rs1360365695, COSV99395982; called by muse, mutect2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 25/57 reads (44%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RPL13A | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.046); catalogued as rs1436005787, COSV99569364; called by muse, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 14/23 reads (61%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPL6 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.069); catalogued as rs781175091, COSV99176122; called by muse, mutect2, varscan2
- RSRC1 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.979); catalogued as rs769143511, COSV99905891, COSV99907311; called by muse, mutect2, varscan2
- RUBCNL | c.1364T>C p.L455P | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100528975; called by muse, mutect2
- RWDD2B | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.055); catalogued as rs146828876; called by muse, mutect2, varscan2
- RXFP3 | c.1306C>T p.P436S | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as COSV100347468; called by muse, mutect2, varscan2
- SAMD9L | c.4224del p.K1408Nfs*10 | Frame Shift Del (DEL) | VAF 33/88 reads (38%) | catalogued as rs759143613, COSV59085428; called by mutect2, pindel, varscan2
- SBF1 | c.3228del p.S1077Afs*28 | Frame Shift Del (DEL) | VAF 18/55 reads (33%) | catalogued as rs771002611; called by mutect2, pindel, varscan2
- SBF2 | c.1860G>T p.Q620H | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99813849; called by muse, mutect2, varscan2
- SCLT1 | c.1312G>T p.G438* | Nonsense Mutation (SNP) | VAF 23/41 reads (56%) | catalogued as COSV99827914; called by muse, mutect2, varscan2
- SCN2A | c.530G>T p.R177M | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99331052; called by muse, mutect2, varscan2
- SCPEP1 | c.1076C>T p.A359V | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.345); catalogued as COSV99227774; called by muse, mutect2, varscan2
- SCRIB | c.3209C>T p.T1070M | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781978489, COSV57590890; called by muse, mutect2, varscan2
- SDF4 | c.1034T>C p.V345A | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as COSV99767547; called by muse, varscan2
- SEMA6D | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199606505, COSV100316787; called by muse, mutect2, varscan2
- SEPTIN2 | c.85C>T p.R29* | Nonsense Mutation (SNP) | VAF 11/35 reads (31%) | catalogued as rs764085863, COSV100764909, COSV63472064; called by muse, mutect2, varscan2
- SERBP1 | c.1141C>T p.R381C (on ENST00000370995 / NM_001018067.2; = p.R360C on NM_015640.4) | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs781357375, COSV63413187; called by muse, mutect2, varscan2
- SERPINA7 | c.1220G>T p.G407V | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100568270; called by muse, mutect2, varscan2
- SGK3 | c.783C>A p.H261Q | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV100616650; called by muse, mutect2, varscan2
- SGMS1 | c.970T>G p.L324V | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.557); catalogued as COSV100693284; called by muse, mutect2, varscan2
- SIGLEC6 | c.754+2T>C p.X252_splice | Splice Site (SNP) | VAF 25/51 reads (49%) | catalogued as COSV100585288; called by muse, mutect2, varscan2
- SLC15A2 | c.1255T>G p.L419V | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.241); catalogued as COSV99815388; called by muse, mutect2
- SLC17A1 | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs181733237, COSV99765693; called by muse, mutect2, varscan2
- SLC17A3 | c.869G>T p.R290M | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100399158; called by muse, mutect2, varscan2
- SLC18A3 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV100340004; called by muse, mutect2, varscan2
- SLC19A2 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs558617037, CD011876, COSV52546831; called by muse, varscan2
- SLC23A1 | c.911G>A p.R304H | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.95); catalogued as rs866364914, COSV100811953; called by muse, mutect2
- SLC25A5 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.168); catalogued as COSV58627130; called by muse, mutect2, varscan2
- SLC2A2 | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as COSV100049242; called by mutect2, varscan2
- SLC2A5 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.75); PolyPhen benign (0.121); catalogued as rs138910454; called by muse, mutect2, varscan2
- SLC34A2 | c.1741C>T p.R581C | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.794); catalogued as COSV65942013; called by muse, mutect2, varscan2
- SLC35F5 | c.742del p.C248Afs*22 | Frame Shift Del (DEL) | VAF 11/24 reads (46%) | catalogued as rs577214214; called by mutect2, varscan2
- SLC36A1 | c.554C>T p.T185M | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.727); catalogued as rs933415871, COSV99695494; called by muse, mutect2, varscan2
- SLC39A9 | c.791C>A p.P264H | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99220295; called by muse, mutect2, varscan2
- SLC6A13 | c.1349C>T p.A450V | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.895); catalogued as rs756578408, CM124495, COSV58255132; called by muse, mutect2, varscan2
- SLC6A9 | c.1220G>A p.S407N (on ENST00000360584 / NM_201649.4; = p.S353N on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100746159; called by muse, mutect2, varscan2
- SMARCAD1 | c.1040del p.N347Mfs*24 | Frame Shift Del (DEL) | VAF 13/35 reads (37%) | catalogued as rs754697669; called by mutect2, varscan2
- SMCHD1 | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs1227032781, COSV55252896; called by muse, mutect2, varscan2
- SMG9 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV99526696; called by muse, mutect2
- SMPD1 | c.1661C>T p.A554V | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as COSV100192595; called by muse, mutect2
- SNTG1 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.459); catalogued as COSV99382937; called by muse, mutect2, varscan2
- SOBP | c.1544C>T p.A515V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as COSV100433015; called by muse, mutect2, varscan2
- SOX6 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as rs1306342622, COSV100321832; called by muse, mutect2, varscan2
- SPANXN3 | c.71del p.N24Mfs*12 | Frame Shift Del (DEL) | VAF 33/83 reads (40%) | catalogued as rs781940283; called by mutect2, varscan2
- SPICE1 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV99871202; called by muse, mutect2, varscan2
- SPNS3 | c.1206del p.T403Rfs*64 | Frame Shift Del (DEL) | VAF 19/47 reads (40%) | catalogued as COSV100337037; called by mutect2, pindel, varscan2
- SPNS3 | c.1382del p.G461Afs*6 | Frame Shift Del (DEL) | VAF 17/50 reads (34%) | catalogued as rs756918252; called by mutect2, pindel, varscan2
- SPTBN1 | c.247C>T p.R83* | Nonsense Mutation (SNP) | VAF 30/78 reads (38%) | catalogued as COSV61693274; called by muse, mutect2, varscan2
- SPTLC3 | c.511C>A p.L171I | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100983047; called by muse, mutect2, varscan2
- SQSTM1 | c.838_840del p.E280del | In Frame Del (DEL) | VAF 13/40 reads (33%) | catalogued as rs752009611; called by pindel, varscan2
- SRD5A3 | c.229T>C p.S77P | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.322); catalogued as COSV99948041; called by muse, mutect2, varscan2
- SREBF1 | c.1948G>T p.G650W | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99888658; called by muse, mutect2, varscan2
- SSB | c.578del p.N193Mfs*13 | Frame Shift Del (DEL) | VAF 14/28 reads (50%) | catalogued as rs753297385; called by mutect2, varscan2
- SSH3 | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.691); catalogued as rs201531520, COSV100354490; called by muse, mutect2, varscan2
- STAT2 | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs374561860; called by muse, mutect2, varscan2
- STAT4 | c.1501C>T p.Q501* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as COSV100636022; called by muse, mutect2, varscan2
- STYK1 | c.935T>C p.F312S | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99311807; called by muse, mutect2, varscan2
- SUGP2 | c.3068G>A p.G1023D | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750911231, COSV100431776; called by muse, mutect2, varscan2
- SUMO2 | c.272C>T p.T91M | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.37); catalogued as rs1204753119, COSV58813600; called by muse, mutect2, varscan2
- SYCP2 | c.4157C>T p.T1386M | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs145233078; called by mutect2, varscan2
- SYNE1 | c.2650A>G p.T884A (on ENST00000367255 / NM_182961.4; = p.T891A on NM_033071.3) | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV54925437, COSV99559914; called by muse, mutect2, varscan2
- SYNE2 | c.6227T>C p.L2076P | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.187); catalogued as COSV100647357; called by muse, mutect2, varscan2
- SYT17 | c.197G>A p.S66N | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs753643002, COSV62547814; called by muse, mutect2, varscan2
- SZT2 | c.5933G>C p.S1978T (on ENST00000634258 / NM_001365999.1; = p.S1921T on NM_015284.4) | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.761); catalogued as COSV100987093; called by muse, mutect2, varscan2
- TACC2 | c.7814C>T p.S2605L (on ENST00000334433; = p.S683L on NM_006997.4) | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV99586928; called by muse, mutect2, varscan2
- TBC1D16 | c.110T>G p.I37S | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as COSV100187931; called by muse, mutect2, varscan2
- TBCD | c.3287G>A p.C1096Y | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100833003; called by muse, mutect2
- TEAD2 | c.637C>A p.P213T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as COSV100246520; called by muse, mutect2
- TECRL | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV67091663; called by muse, mutect2, varscan2
- TET1 | c.65del p.K22Rfs*23 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as rs1196853334; called by mutect2, varscan2
- TFAM | c.441del p.E148Sfs*2 | Frame Shift Del (DEL) | VAF 11/23 reads (48%) | catalogued as rs544132101; called by mutect2, varscan2
- TFAP2D | c.538-1G>T p.X180_splice | Splice Site (SNP) | VAF 27/52 reads (52%) | catalogued as COSV99145839; called by muse, mutect2, varscan2
- TGIF2LX | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.477); catalogued as COSV99383272, COSV99383517; called by muse, mutect2, varscan2
- TGM7 | c.1748G>A p.R583H | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs199638924; called by muse, mutect2, varscan2
- THRA | c.1057G>A p.V353I | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.81); PolyPhen benign (0.005); catalogued as rs766284607, COSV52847465; called by muse, mutect2, varscan2
- TLE1 | c.1621G>A p.D541N | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs201140985; called by muse, mutect2, varscan2
- TLE6 | c.1595C>T p.A532V (on ENST00000246112 / NM_001143986.2; = p.A409V on NM_024760.3) | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs757810781, COSV53578228; called by muse, mutect2, varscan2
- TLK1 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1317989051, COSV100687965; called by muse, mutect2
- TM9SF2 | c.130G>T p.V44F | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.313); catalogued as COSV100816403; called by muse, mutect2, varscan2
- TMC5 | c.253G>A p.G85S | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.012); catalogued as COSV101196662; called by muse, mutect2, varscan2
- TMEM205 | c.85G>A p.V29M | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.754); catalogued as rs746159701, COSV100712276; called by muse, mutect2, varscan2
- TMEM266 | c.456G>T p.E152D | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101189592; called by muse, mutect2, varscan2
- TMEM94 | c.913C>A p.P305T | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV100050302; called by muse, mutect2, varscan2
- TMUB1 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); catalogued as rs368011829, COSV99879678; called by muse, mutect2, varscan2
- TNRC18 | c.3433C>T p.R1145W | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs374367634; called by muse, mutect2
- TNRC18 | c.2560C>T p.Q854* | Nonsense Mutation (SNP) | VAF 11/17 reads (65%) | catalogued as COSV101269627; called by muse, mutect2, varscan2
- TNRC6B | c.2486C>A p.P829Q | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as COSV100109115; called by muse, mutect2, varscan2
- TNXB | c.11500G>A p.V3834M (on ENST00000647633; = p.V3587M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.394); catalogued as rs560288296, COSV100925955; called by muse, mutect2, varscan2
- TP73 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs771056792, COSV100601101, COSV100601679; called by muse, mutect2, varscan2
- TPO | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.56); catalogued as rs772197481, COSV61097198; called by muse, mutect2, varscan2
- TRANK1 | c.4298G>A p.R1433H | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1273387391, COSV57146495; called by muse, mutect2, varscan2
- TRIM41 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs775605642, COSV100163110; called by muse, mutect2, varscan2
- TRIM8 | c.966del p.T323Lfs*6 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | catalogued as COSV56659451; called by mutect2, pindel, varscan2
- TTC14 | c.781G>A p.G261R | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.564); catalogued as rs1392590719, COSV99931969; called by muse, mutect2, varscan2
- TTC17 | c.2144C>T p.A715V | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.33); PolyPhen benign (0.156); catalogued as COSV99235130; called by muse, mutect2, varscan2
- TTC17 | c.2725C>T p.R909C | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs747480720, COSV50013740; called by muse, mutect2, varscan2
- TTC21A | c.3479G>A p.S1160N | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV99826797; called by muse, mutect2, varscan2
- TTC25 | c.1756T>C p.S586P | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV101102922; called by muse, mutect2
- TTC37 | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.762); catalogued as rs772142569, COSV100706542; called by muse, mutect2, varscan2
- TTYH2 | c.1111C>T p.H371Y | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs1224656507, COSV99482957; called by muse, mutect2, varscan2
- TULP2 | c.430G>A p.V144M | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.153); catalogued as rs769337401, COSV99667636, COSV99667786; called by muse, mutect2, varscan2
- UBA6 | c.1866A>G p.I622M | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100451645; called by muse, mutect2, varscan2
- UBASH3A | c.668-1G>A p.X223_splice | Splice Site (SNP) | VAF 14/36 reads (39%) | catalogued as COSV99369466; called by muse, mutect2, varscan2
- UGP2 | c.441+2T>C p.X147_splice | Splice Site (SNP) | VAF 9/25 reads (36%) | catalogued as COSV100451584; called by muse, mutect2, varscan2
- UNC93A | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs372539280, COSV100023245; called by muse, mutect2, varscan2
- UPRT | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.074); catalogued as rs1003876010, COSV64920500; called by muse, mutect2, varscan2
- URI1 | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs768120343, COSV100368951, COSV56353299; called by mutect2, varscan2
- USF3 | c.439del p.I147Lfs*22 | Frame Shift Del (DEL) | VAF 26/54 reads (48%) | catalogued as rs747493460; called by mutect2, varscan2
- USP36 | c.2651C>T p.A884V | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.031); catalogued as rs748890796, COSV100361411, COSV100361833; called by muse, mutect2, varscan2
- USP42 | c.3707del p.K1236Rfs*92 | Frame Shift Del (DEL) | VAF 8/14 reads (57%) | catalogued as rs759165525, COSV60363391; called by mutect2, varscan2
- VAMP5 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs375941183; called by muse, mutect2, varscan2
- VCX | c.567G>T p.Q189H | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.25); catalogued as COSV58232004; called by muse, varscan2
- VCX3A | c.507G>T p.Q169H | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.25); catalogued as COSV101129858; called by muse, varscan2
- VDAC3 | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.75); catalogued as COSV99195110; called by muse, mutect2, varscan2
- VPS13D | c.4305T>A p.N1435K | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.105); catalogued as COSV50643575, COSV99166092; called by muse, mutect2, varscan2
- VWCE | c.1466del p.P489Hfs*11 | Frame Shift Del (DEL) | VAF 6/56 reads (11%) | catalogued as rs753714493; called by pindel, varscan2
- WDR36 | c.2663G>A p.R888H | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.543); catalogued as rs148737719; called by muse, mutect2, varscan2
- WDR90 | c.3056C>T p.P1019L | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs754501977, COSV53470405; called by muse, mutect2, varscan2
- WFDC8 | c.362C>T p.T121I | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.206); catalogued as rs767661325, COSV51491301; called by muse, mutect2, varscan2
- WNK4 | c.2305G>A p.A769T | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV99890011; called by muse, mutect2
- WRNIP1 | c.1312G>A p.G438S | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867029038, COSV66356158; called by muse, mutect2, varscan2
- XAGE3 | c.137C>A p.P46H | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.012); catalogued as COSV100655660, COSV60569118; called by muse, varscan2
- ZBTB24 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.024); catalogued as COSV100018398; called by muse, mutect2, varscan2
- ZC3H18 | c.97G>T p.G33W | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as COSV99963996; called by muse, mutect2, varscan2
- ZC3HAV1 | c.1420G>A p.A474T | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs568024631, COSV54301429; called by muse, mutect2, varscan2
- ZFHX3 | c.9670C>T p.L3224F | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.039); catalogued as rs759757430, COSV99196688; called by muse, mutect2, varscan2
- ZFP14 | c.533G>T p.R178M | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as COSV99525111; called by muse, mutect2, varscan2
- ZFR | c.2177A>G p.Y726C | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs1465041479, COSV54050363, COSV99415699; called by muse, mutect2
- ZIC3 | c.889T>C p.C297R | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM160396, COSV99798733; called by muse, mutect2, varscan2
- ZNF236 | c.3737C>T p.T1246M | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1292835726, COSV99470082; called by muse, mutect2, varscan2
- ZNF251 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.155); catalogued as rs1449023740, COSV52957556; called by muse, mutect2, varscan2
- ZNF609 | c.2201del p.K734Rfs*12 | Frame Shift Del (DEL) | VAF 12/17 reads (71%) | catalogued as rs760768847; called by mutect2, varscan2
- ZNF622 | c.1320G>A p.M440I | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV100433042; called by muse, mutect2, varscan2
- ZNF74 | c.919G>A p.G307S | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs755062379, COSV62621365; called by muse, mutect2, varscan2
- ZNF98 | c.306T>A p.N102K | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as rs1568289712, COSV63335140, COSV63335366; called by muse, mutect2, varscan2
- ZP1 | c.1395del p.F466Sfs*25 | Frame Shift Del (DEL) | VAF 7/21 reads (33%) | catalogued as rs771388504; called by mutect2, pindel, varscan2
- ZSWIM3 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV99666396; called by muse, mutect2, varscan2
- ABO | c.801del p.F268Sfs*20 | Frame Shift Del (DEL) | VAF 21/58 reads (36%) | called by mutect2, pindel, varscan2
- ACAN | c.1097dup p.E367* | Frame Shift Ins (INS) | VAF 7/54 reads (13%) | called by mutect2, pindel, varscan2
- ADAMTSL4 | c.2693del p.P898Lfs*50 | Frame Shift Del (DEL) | VAF 22/57 reads (39%) | called by mutect2, pindel, varscan2
- ANKRD44 | c.1941_1942del p.L648Vfs*36 | Frame Shift Del (DEL) | VAF 13/37 reads (35%) | called by pindel, varscan2
- ANKRD50 | c.3704del p.P1235Hfs*8 | Frame Shift Del (DEL) | VAF 11/32 reads (34%) | called by mutect2, pindel, varscan2
- ARID4B | c.2815del p.T939Rfs*2 | Frame Shift Del (DEL) | VAF 20/55 reads (36%) | called by mutect2, pindel, varscan2
- BEND5 | c.1051_1052del p.K351Efs*6 | Frame Shift Del (DEL) | VAF 22/48 reads (46%) | called by mutect2, varscan2
- CAGE1 | c.1295dup p.N432Kfs*2 (on ENST00000512086; = p.N296Kfs*2 on NM_205864.3) | Frame Shift Ins (INS) | VAF 10/32 reads (31%) | called by mutect2, varscan2
- CCNO | c.1040dup p.S348Efs*23 | Frame Shift Ins (INS) | VAF 21/53 reads (40%) | called by mutect2, pindel, varscan2
- CENPE | c.5986del p.I1996Lfs*7 | Frame Shift Del (DEL) | VAF 9/71 reads (13%) | called by mutect2, pindel, varscan2
- CLASRP | c.284del p.P95Lfs*81 | Frame Shift Del (DEL) | VAF 23/58 reads (40%) | called by mutect2, pindel, varscan2
- CSMD3 | c.10920dup p.A3641Cfs*13 (on ENST00000297405 / NM_001363185.1; = p.A3472Cfs*13 on NM_052900.3) | Frame Shift Ins (INS) | VAF 7/20 reads (35%) | called by mutect2, varscan2
- CTDP1 | c.1440dup p.K481Efs*49 | Frame Shift Ins (INS) | VAF 10/20 reads (50%) | called by mutect2, varscan2
- DDX17 | c.488del p.G163Efs*20 | Frame Shift Del (DEL) | VAF 23/65 reads (35%) | called by mutect2, pindel, varscan2
- DNAH17 | c.12390del p.N4131Tfs*34 | Frame Shift Del (DEL) | VAF 19/42 reads (45%) | called by mutect2, pindel, varscan2
- DNAJC22 | c.47del p.G16Afs*21 | Frame Shift Del (DEL) | VAF 24/62 reads (39%) | called by mutect2, pindel, varscan2
- DST | c.11246del p.K3749Rfs*7 (on ENST00000361203 / NM_001374722.1; = p.K1337Rfs*7 on NM_015548.5) | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | called by mutect2, pindel, varscan2
- EIF4G3 | c.1689del p.V564* | Frame Shift Del (DEL) | VAF 16/26 reads (62%) | called by mutect2, varscan2
- EML5 | c.1987del p.S663Vfs*71 | Frame Shift Del (DEL) | VAF 21/43 reads (49%) | called by mutect2, pindel, varscan2
- GDI1 | c.341del p.G114Afs*18 | Frame Shift Del (DEL) | VAF 12/22 reads (55%) | called by mutect2, varscan2
- GK2 | c.30del p.P11Rfs*33 | Frame Shift Del (DEL) | VAF 18/43 reads (42%) | called by mutect2, pindel, varscan2
- GRM3 | c.199C>T p.Q67* | Nonsense Mutation (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- GTF3C1 | c.2890dup p.S964Ffs*26 | Frame Shift Ins (INS) | VAF 10/33 reads (30%) | called by mutect2, pindel, varscan2
- HAPLN2 | c.939del p.L314Sfs*100 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- HIBCH | c.609dup p.G204Rfs*17 | Frame Shift Ins (INS) | VAF 13/43 reads (30%) | called by mutect2, pindel, varscan2
- IFI30 | c.22_24del p.L8del | In Frame Del (DEL) | VAF 22/50 reads (44%) | called by pindel, varscan2
- KCNB1 | c.2206del p.R736Gfs*9 | Frame Shift Del (DEL) | VAF 16/45 reads (36%) | called by mutect2, pindel, varscan2
- KLK1 | c.18del p.C7Afs*97 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | called by mutect2, pindel, varscan2
- LHX1 | c.34C>A p.L12M | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LIX1 | c.224dup p.S76Kfs*12 | Frame Shift Ins (INS) | VAF 9/27 reads (33%) | called by mutect2, pindel, varscan2
- LRP12 | c.472del p.S158Qfs*80 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | called by mutect2, pindel, varscan2
- LRP2 | c.1348dup p.S450Ffs*3 | Frame Shift Ins (INS) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- LTB4R2 | c.1133del p.G378Vfs*47 (on ENST00000528054; = p.G347Vfs*47 on NM_019839.5) | Frame Shift Del (DEL) | VAF 29/66 reads (44%) | called by mutect2, pindel, varscan2
- MAP3K11 | c.1841del p.P614Rfs*27 | Frame Shift Del (DEL) | VAF 24/46 reads (52%) | called by mutect2, varscan2
- MED23 | c.2276del p.N759Mfs*12 | Frame Shift Del (DEL) | VAF 14/25 reads (56%) | called by mutect2, varscan2
- MLLT6 | c.729G>T p.K243N | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- MPHOSPH10 | c.617_618del p.K206Tfs*3 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | called by mutect2, pindel, varscan2
- NCOR2 | c.2925del p.I976Sfs*87 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel, varscan2
- NCOR2 | c.453del p.S152Afs*21 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | called by mutect2, pindel
- NSD1 | c.4591del p.M1531Cfs*43 | Frame Shift Del (DEL) | VAF 25/63 reads (40%) | called by mutect2, pindel, varscan2
- NUP107 | c.613dup p.T205Nfs*23 | Frame Shift Ins (INS) | VAF 16/43 reads (37%) | called by mutect2, pindel, varscan2
- OGFR | c.1975dup p.E659Gfs*58 | Frame Shift Ins (INS) | VAF 33/77 reads (43%) | called by mutect2, pindel, varscan2
- OR4K17 | c.535del p.C179Vfs*12 | Frame Shift Del (DEL) | VAF 16/45 reads (36%) | called by mutect2, pindel, varscan2
- PCNT | c.2818del p.A940Lfs*51 | Frame Shift Del (DEL) | VAF 10/25 reads (40%) | called by mutect2, pindel, varscan2
- PHF1 | c.16del p.R6Gfs*2 | Frame Shift Del (DEL) | VAF 9/30 reads (30%) | called by mutect2, pindel, varscan2
- PLEKHM3 | c.1531_1532del p.S511Ffs*30 | Frame Shift Del (DEL) | VAF 31/75 reads (41%) | called by pindel, varscan2
- PSMC4 | c.598del p.R200Efs*65 | Frame Shift Del (DEL) | VAF 11/37 reads (30%) | called by mutect2, pindel, varscan2
- PTPRS | c.1239dup p.S414Qfs*213 | Frame Shift Ins (INS) | VAF 31/66 reads (47%) | called by mutect2, varscan2
- ROS1 | c.1240del p.I414Lfs*14 | Frame Shift Del (DEL) | VAF 19/45 reads (42%) | called by mutect2, pindel, varscan2
- SBDS | c.677del p.K226Rfs*14 | Frame Shift Del (DEL) | VAF 25/65 reads (38%) | called by mutect2, pindel, varscan2
- SHOC1 | c.4333dup p.*1445Lfs*21 | Frame Shift Ins (INS) | VAF 24/64 reads (38%) | called by mutect2, varscan2
- SKIV2L | c.3521_3522del p.Y1174* | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | called by pindel, varscan2
- SLC16A10 | c.844del p.I282Ffs*9 | Frame Shift Del (DEL) | VAF 8/14 reads (57%) | called by mutect2, varscan2
- TAP2 | c.223del p.L75* | Frame Shift Del (DEL) | VAF 25/60 reads (42%) | called by mutect2, varscan2
- TCERG1 | c.1737del p.G580Efs*5 | Frame Shift Del (DEL) | VAF 24/71 reads (34%) | called by mutect2, pindel, varscan2
- TCF7L1 | c.667del p.R223Gfs*54 | Frame Shift Del (DEL) | VAF 17/44 reads (39%) | called by mutect2, pindel, varscan2
- TEP1 | c.1174del p.R392Afs*22 | Frame Shift Del (DEL) | VAF 10/73 reads (14%) | called by mutect2, pindel, varscan2
- TM6SF1 | c.*3del | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | called by mutect2, pindel, varscan2
- TMEM245 | c.1287del p.G431Efs*5 | Frame Shift Del (DEL) | VAF 21/46 reads (46%) | called by mutect2, pindel, varscan2
- TRAV26-2 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TRBV29-1 | c.323G>A p.C108Y | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRERF1 | c.166del p.H56Tfs*51 | Frame Shift Del (DEL) | VAF 35/90 reads (39%) | called by mutect2, pindel, varscan2
- ZNF594 | c.1530_1531del p.H510Qfs*3 | Frame Shift Del (DEL) | VAF 20/50 reads (40%) | called by mutect2, pindel, varscan2
- A4GALT | c.483C>T p.A161= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs778577677, COSV99966626; called by muse, mutect2, varscan2
- AACS | c.1509C>T p.N503= | Silent (SNP) | VAF 59/154 reads (38%) | catalogued as rs777134166, COSV99907918; called by muse, mutect2, varscan2
- AATK | c.951C>T p.S317= (on ENST00000326724 / NM_001080395.3; = p.S214= on NM_004920.2) | Silent (SNP) | VAF 3/47 reads (6%) | catalogued as rs961047576, COSV58689622; called by muse, mutect2
- ABCA7 | c.264C>T p.G88= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as rs1471242175, COSV99565561; called by muse, mutect2, varscan2
- ABCB1 | c.1416G>A p.V472= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV99712000, COSV99714757; called by muse, mutect2, varscan2
- ABI3BP | c.1848G>A p.E616= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV99426170; called by muse, mutect2, varscan2
- ADAM22 | c.2061T>C p.I687= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV99716426; called by muse, mutect2, varscan2
- ADAM8 | c.1971C>T p.F657= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as rs1250187140, COSV101291651; called by muse, mutect2, varscan2
- ADCY3 | c.306C>T p.S102= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as COSV99568025; called by muse, mutect2, varscan2
- AFG3L2 | c.1386G>A p.A462= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as COSV52316873; called by muse, mutect2
- ALKBH1 | c.822C>T p.D274= | Silent (SNP) | VAF 18/31 reads (58%) | catalogued as rs1201361228, COSV99380519; called by muse, mutect2, varscan2
- ANGPTL4 | c.1170G>A p.L390= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV100035069; called by muse, mutect2, varscan2
- ANO3 | c.2547C>A p.P849= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV99882052; called by muse, mutect2, varscan2
- ARHGAP39 | c.1473G>A p.T491= | Silent (SNP) | VAF 39/77 reads (51%) | catalogued as rs771056325, COSV99430821; called by muse, mutect2, varscan2
- ARHGEF9 | c.1161C>T p.S387= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as COSV99491626; called by muse, mutect2, varscan2
- ARVCF | c.2364C>A p.S788= | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as COSV99258547; called by muse, mutect2, varscan2
- ASCC2 | c.1482C>T p.Y494= | Silent (SNP) | VAF 23/42 reads (55%) | catalogued as COSV100316189; called by muse, mutect2, varscan2
- ATN1 | c.1473G>A p.Q491= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs782425213; called by muse, varscan2
- ATXN2L | c.2346G>T p.T782= | Silent (SNP) | VAF 28/63 reads (44%) | catalogued as COSV100294054, COSV100294159, COSV57372588; called by muse, mutect2, varscan2
- B3GNT6 | c.180G>A p.P60= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV100845772; called by muse, mutect2
- BACH2 | c.153C>T p.H51= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV99998890; called by muse, mutect2, varscan2
- BIN1 | c.1311T>C p.A437= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV99387836; called by muse, mutect2, varscan2
- BPTF | c.2547C>T p.R849= | Silent (SNP) | VAF 27/51 reads (53%) | catalogued as rs763441304, COSV100075820, COSV58833640; called by muse, mutect2, varscan2
- BUB1 | c.1035G>A p.Q345= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV100241143; called by muse, mutect2, varscan2
- C12orf50 | c.1056C>T p.R352= | Silent (SNP) | VAF 50/101 reads (50%) | catalogued as COSV100072159; called by muse, mutect2, varscan2
- CACNA1G | c.4866G>A p.G1622= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV100661634; called by muse, mutect2, varscan2
- CARD8 | c.1020C>T p.D340= (on ENST00000651546 / NM_001184900.3; = p.D290= on NM_014959.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as rs539295882, COSV100751062; called by muse, mutect2, varscan2
- CBX4 | c.738T>C p.I246= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as COSV99490297; called by muse, mutect2, varscan2
- CCDC130 | c.342C>T p.G114= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as rs374550969, COSV55583031; called by muse, mutect2, varscan2
- CCDC69 | c.774G>A p.R258= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as COSV100815144; called by muse, mutect2, varscan2
- CCNQ | c.582G>A p.A194= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as rs781829925, COSV99367943; called by muse, mutect2, varscan2
- CELSR1 | c.8370G>A p.A2790= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs757230082, COSV99417745; called by muse, mutect2, varscan2
- CFAP43 | c.1626G>A p.S542= | Silent (SNP) | VAF 32/67 reads (48%) | catalogued as rs747748851, COSV99530594, COSV99531031; called by muse, mutect2, varscan2
- CHD3 | c.3561C>T p.R1187= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as rs199967836, COSV57880695; called by muse, mutect2, varscan2
- CIAO1 | c.771C>T p.D257= | Silent (SNP) | VAF 23/45 reads (51%) | catalogued as COSV99302562; called by muse, mutect2, varscan2
- CILP2 | c.1824G>A p.T608= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as rs773247413, COSV99364547; called by muse, mutect2, varscan2
- CKAP5 | c.1143G>A p.L381= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as COSV56364126, COSV56372800; called by muse, mutect2, varscan2
- CLEC10A | c.879C>T p.D293= (on ENST00000254868 / NM_182906.4; = p.D269= on NM_006344.4) | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs763602748, COSV99644659; called by muse, mutect2, varscan2
- CLTC | c.2013G>A p.L671= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as rs1363653641, COSV99292017; called by muse, mutect2, varscan2
- CMA1 | c.726G>A p.Q242= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV99157246; called by muse, mutect2
- CNTN2 | c.924G>A p.A308= | Silent (SNP) | VAF 23/44 reads (52%) | catalogued as rs754100959, COSV100084866; called by muse, mutect2, varscan2
- COLGALT1 | c.960G>A p.P320= | Silent (SNP) | VAF 30/72 reads (42%) | catalogued as rs1391119838, COSV53107327, COSV99394948; called by muse, mutect2, varscan2
- COLGALT1 | c.1641T>C p.H547= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as COSV99394950; called by muse, mutect2, varscan2
- CRISP1 | c.105C>T p.T35= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs145871288; called by muse, mutect2, varscan2
- CUBN | c.8988T>C p.A2996= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV100912425; called by muse, mutect2
- DCLK3 | c.267G>A p.A89= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs1274458490, COSV69363039; called by muse, mutect2, varscan2
- DDB1 | c.1386C>T p.N462= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as rs750382745, COSV57101564; called by muse, mutect2, varscan2
- DENND2A | c.747C>T p.N249= | Silent (SNP) | VAF 28/58 reads (48%) | catalogued as COSV52047961; called by muse, mutect2, varscan2
- DHCR7 | c.1086C>T p.R362= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs1459497627, COSV100831861; called by muse, mutect2, varscan2
- DNAH1 | c.7071G>T p.L2357= | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as COSV101325447; called by muse, mutect2, varscan2
- DNAH11 | c.11877C>T p.F3959= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV100178594; called by muse, mutect2, varscan2
- DPPA5 | c.96G>A p.L32= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV100951491; called by muse, mutect2, varscan2
- DSCAM | c.5310G>A p.L1770= | Silent (SNP) | VAF 33/73 reads (45%) | catalogued as rs1244810001, COSV101259753; called by muse, mutect2, varscan2
- EGFR | c.777G>A p.T259= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs751873368, COSV51797542, COSV99286584; called by muse, mutect2, varscan2
- EHMT2 | c.1788C>T p.C596= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as rs766303516, COSV64996895; called by muse, mutect2, varscan2
- EPB41L3 | c.1632G>A p.P544= | Silent (SNP) | VAF 27/52 reads (52%) | catalogued as rs201925314, COSV59473284; called by muse, mutect2, varscan2
- EXPH5 | c.2262C>T p.N754= | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as rs775406227, COSV56199053; called by muse, mutect2, varscan2
- FAF2 | c.897C>T p.A299= | Silent (SNP) | VAF 25/47 reads (53%) | catalogued as COSV99990380; called by muse, mutect2, varscan2
- FARSA | c.490C>T p.L164= | Silent (SNP) | VAF 27/60 reads (45%) | catalogued as COSV100108771; called by muse, mutect2, varscan2
- FBXL2 | c.858C>T p.H286= | Silent (SNP) | VAF 37/78 reads (47%) | catalogued as rs149945780; called by muse, mutect2, varscan2
- FCHSD2 | c.1323C>T p.T441= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs543596845, COSV100238149, COSV60814457; called by muse, mutect2, varscan2
- FURIN | c.1467G>A p.A489= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs772524475, COSV99184654; called by muse, mutect2, varscan2
- FUT5 | c.828C>T p.N276= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as rs755710824, COSV99398659; called by muse, mutect2, varscan2
- FUZ | c.1174C>T p.L392= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as COSV100571100; called by muse, mutect2, varscan2
- GIT2 | c.1722C>T p.S574= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs745681173, COSV100188965; called by muse, varscan2
- GMEB2 | c.114C>T p.T38= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as rs1369004850, COSV99823567; called by muse, mutect2, varscan2
- GPC5 | c.795G>A p.A265= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as rs749523673, COSV65597230; called by muse, mutect2, varscan2
- GRIA3 | c.279G>A p.Q93= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV52066469, COSV52082605; called by muse, mutect2, varscan2
- GRIK2 | c.870C>A p.S290= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV100024956; called by muse, mutect2, varscan2
- GTSE1 | c.1485G>A p.Q495= | Silent (SNP) | VAF 23/44 reads (52%) | catalogued as rs568343475, COSV101483201; called by muse, mutect2, varscan2
- HAUS7 | c.186G>A p.K62= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as COSV100444065, COSV57850202; called by muse, mutect2, varscan2
- HCN2 | c.1311C>T p.S437= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as rs756441487, COSV99241545, COSV99241604; called by muse, mutect2, varscan2
- HERC2 | c.14082C>T p.I4694= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as rs768590947, COSV55306061, COSV55346140; called by muse, mutect2, varscan2
- HKDC1 | c.1560G>A p.P520= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs766012049, COSV63575550, COSV63577752; called by muse, mutect2, varscan2
- HMBS | c.789G>A p.V263= | Silent (SNP) | VAF 31/72 reads (43%) | catalogued as rs1487819553, COSV99597906; called by muse, mutect2, varscan2
- HOMER2 | c.129C>T p.N43= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV100420296; called by muse, mutect2, varscan2
- HOXC6 | c.72C>T p.V24= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV54537632; called by muse, mutect2, varscan2
- HSF2 | c.462T>C p.N154= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV100869670; called by muse, mutect2, varscan2
- HTT | c.9261C>T p.D3087= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as COSV100750638; called by muse, mutect2, varscan2
- INTS3 | c.1158C>T p.V386= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as rs201003265, COSV59679905; called by muse, mutect2, varscan2
- ITGAL | c.1404C>T p.D468= | Silent (SNP) | VAF 38/92 reads (41%) | catalogued as rs373129629, COSV63323162; called by muse, mutect2, varscan2
- ITPR3 | c.7311G>T p.S2437= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV100953606; called by muse, mutect2, varscan2
- JAG2 | c.771C>A p.T257= | Silent (SNP) | VAF 21/38 reads (55%) | catalogued as COSV100078141; called by muse, mutect2, varscan2
- KCNJ3 | c.330C>T p.G110= | Silent (SNP) | VAF 36/81 reads (44%) | catalogued as COSV54531359; called by muse, mutect2, varscan2
- KCNV2 | c.639G>A p.R213= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs1439836141, COSV101172452; called by muse, mutect2, varscan2
- KIAA0319L | c.3102C>T p.N1034= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as rs781641046, COSV100357256; called by muse, mutect2, varscan2
- KIF14 | c.4575T>C p.H1525= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV100950784; called by muse, mutect2, varscan2
- KIF5C | c.960C>T p.F320= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as rs764512878, COSV101276118; called by muse, mutect2, varscan2
- KRT82 | c.507C>T p.F169= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs1443392350, COSV99233346; called by muse, mutect2, varscan2
- LDB2 | c.360C>T p.C120= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as rs751384648, COSV58781055; called by muse, mutect2, varscan2
- LHPP | c.642C>T p.D214= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as rs750853265, COSV64332192; called by muse, mutect2, varscan2
- LRP1 | c.4461C>T p.Y1487= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs771406021, COSV54525115; called by muse, mutect2, varscan2
- LRRC37A3 | c.3165A>G p.T1055= | Silent (SNP) | VAF 84/177 reads (47%) | catalogued as COSV100140972; called by muse, mutect2, varscan2
- LTBP2 | c.3240C>T p.N1080= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs751397943, COSV56207079; called by muse, mutect2, varscan2
- LTBP2 | c.1971G>A p.S657= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as rs754925929, COSV100000089; called by muse, mutect2, varscan2
- LYST | c.11289C>T p.G3763= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs779752850, COSV101088989; called by muse, mutect2
- MDN1 | c.5271T>C p.V1757= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as COSV101021114; called by muse, mutect2, varscan2
- MEIS2 | c.798C>T p.D266= (on ENST00000561208 / NM_170675.5; = p.D253= on NM_002399.3) | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs1261255075, COSV99576193; called by muse, mutect2, varscan2
- MKNK1 | c.885C>T p.A295= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs1484870094, COSV100361166; called by muse, mutect2, varscan2
- MOB1B | c.162T>C p.N54= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV100511501; called by muse, mutect2, varscan2
- MOB4 | c.27G>A p.V9= | Silent (SNP) | VAF 34/76 reads (45%) | catalogued as COSV99291005; called by muse, mutect2, varscan2
- MRPL55 | c.318C>T p.Y106= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as rs773798884, COSV99686792; called by muse, mutect2, varscan2
- MRPS18B | c.255A>G p.V85= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV99457645; called by muse, mutect2, varscan2
- MTMR12 | c.603T>C p.H201= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV99373509; called by muse, mutect2, varscan2
- MXRA5 | c.6438G>A p.A2146= | Silent (SNP) | VAF 24/44 reads (55%) | catalogued as COSV54228712; called by muse, mutect2, varscan2
- MYBL1 | c.651T>C p.H217= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as COSV101576514; called by muse, mutect2, varscan2
- MYO1F | c.1167C>T p.G389= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV100596566; called by muse, mutect2, varscan2
- MYOM2 | c.3342G>A p.L1114= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV100037278; called by muse, mutect2, varscan2
- NAT1 | c.108C>A p.P36= | Silent (SNP) | VAF 27/58 reads (47%) | catalogued as COSV100306498; called by muse, mutect2, varscan2
- NCOA7 | c.624G>A p.S208= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs973213076, COSV99996852; called by muse, mutect2, varscan2
- NRAP | c.3804T>C p.S1268= (on ENST00000359988 / NM_001322945.2; = p.S1233= on NM_006175.4) | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as COSV100748318; called by muse, mutect2, varscan2
- NSF | c.1515C>T p.N505= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as rs756947942, COSV99833773; called by muse, mutect2, varscan2
- OSMR | c.2004G>A p.A668= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as rs906816971, COSV99952797; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.36T>C p.S12= (on ENST00000259318 / NM_001136562.3; = p.S243= on NM_007203.5) | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV99395045; called by muse, mutect2, varscan2
- PARD3 | c.2412C>T p.A804= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as rs781058544, COSV60744737; called by muse, mutect2, varscan2
- PCDH17 | c.333C>T p.N111= | Silent (SNP) | VAF 14/20 reads (70%) | catalogued as rs1363153167, COSV64972520; called by muse, mutect2, varscan2
- PCDHA3 | c.2145G>A p.L715= | Silent (SNP) | VAF 22/40 reads (55%) | catalogued as rs782025837, COSV100793311; called by muse, mutect2, varscan2
- PCDHA6 | c.1554C>T p.Y518= | Silent (SNP) | VAF 50/130 reads (38%) | catalogued as COSV100971387; called by muse, mutect2, varscan2
- PCSK4 | c.990C>T p.R330= | Silent (SNP) | VAF 65/148 reads (44%) | catalogued as rs141320211; called by muse, mutect2, varscan2
- PCSK4 | c.720C>T p.I240= | Silent (SNP) | VAF 23/43 reads (53%) | catalogued as rs767882439, COSV99278571; called by muse, mutect2, varscan2
- PDIA5 | c.84G>A p.S28= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as rs565710424, COSV60247396; called by muse, mutect2, varscan2
- PGAM1 | c.267G>A p.E89= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as COSV58356341; called by muse, mutect2, varscan2
- PHLPP2 | c.3708T>C p.Y1236= | Silent (SNP) | VAF 42/87 reads (48%) | catalogued as COSV100673613; called by muse, mutect2, varscan2
- PI4K2A | c.1074C>A p.S358= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV101034178; called by muse, mutect2, varscan2
- PIGG | c.2676C>T p.Y892= (on ENST00000453061 / NM_001127178.3; = p.Y884= on NM_017733.4) | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs1436083431, COSV56317184; called by muse, mutect2, varscan2
- PIMREG | c.99C>T p.V33= | Silent (SNP) | VAF 22/41 reads (54%) | catalogued as COSV100002441; called by muse, mutect2, varscan2
- PRSS53 | c.981C>T p.G327= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs371720280, COSV99762197; called by muse, mutect2, varscan2
- PTCH1 | c.3669G>A p.S1223= | Silent (SNP) | VAF 27/52 reads (52%) | catalogued as rs780515178, COSV100108119; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- PTK6 | c.699G>A p.Q233= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV53918343; called by muse, mutect2, varscan2
- PTPRZ1 | c.4698A>G p.T1566= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as COSV101099918; called by muse, mutect2, varscan2
- RAB5C | c.201C>T p.D67= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as COSV100651404, COSV60526639; called by muse, mutect2, varscan2
- RHBDL3 | c.1038C>T p.G346= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs953921028, COSV99283637; called by muse, mutect2, varscan2
- RICTOR | c.4209G>A p.L1403= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as COSV99704722; called by muse, mutect2, varscan2
- RNF112 | c.1164C>T p.Y388= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs771130689, COSV101465426, COSV71327069; called by muse, mutect2, varscan2
- ROBO4 | c.1713C>T p.G571= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as rs752616910, COSV60622958; called by muse, mutect2, varscan2
- ROR2 | c.1137G>A p.T379= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as rs767456619, COSV65216122; called by muse, mutect2, varscan2
- RPS6KA6 | c.69G>A p.A23= | Silent (SNP) | VAF 39/73 reads (53%) | catalogued as rs1430779079, COSV99424571; called by muse, mutect2, varscan2
- RRH | c.351G>A p.T117= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as rs369711712; called by muse, mutect2, varscan2
- SCAF1 | c.2386C>A p.R796= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs753735532, COSV62183461; called by muse, mutect2, varscan2
- SDC2 | c.450T>C p.I150= | Silent (SNP) | VAF 27/63 reads (43%) | catalogued as COSV100143245; called by muse, mutect2, varscan2
- SEC24A | c.789C>T p.Y263= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs770678608, COSV59745892; called by muse, mutect2, varscan2
- SGCA | c.492C>T p.L164= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV100006656; called by muse, mutect2, varscan2
- SLC35A4 | c.231C>A p.P77= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV100021259; called by muse, mutect2, varscan2
- SLC4A4 | c.1413G>A p.S471= (on ENST00000264485 / NM_001098484.3; = p.S427= on NM_003759.4) | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs1158151729, COSV99139718; called by muse, mutect2, varscan2
- SLC8B1 | c.1041G>A p.P347= | Silent (SNP) | VAF 23/37 reads (62%) | catalogued as rs747034646, COSV99176675, COSV99176687; called by muse, mutect2
- SLCO6A1 | c.6C>T p.F2= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as COSV65806064; called by muse, mutect2, varscan2
- SMCR8 | c.1446C>T p.S482= | Silent (SNP) | VAF 17/31 reads (55%) | catalogued as rs373126946; called by muse, mutect2, varscan2
- SNAI3 | c.105G>A p.G35= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV100178822; called by muse, mutect2, varscan2
- SOWAHA | c.1293G>A p.S431= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs753498449, COSV101097651; called by muse, varscan2
- SRCIN1 | c.816C>T p.N272= (on ENST00000621492; = p.N238= on NM_025248.3) | Silent (SNP) | VAF 20/43 reads (47%) | called by muse, mutect2, varscan2
- SREBF1 | c.718C>T p.L240= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV99888659; called by muse, mutect2, varscan2
- SRSF4 | c.1446G>A p.S482= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as rs138994362; called by muse, mutect2, varscan2
- ST14 | c.2511C>T p.G837= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as COSV99598637; called by muse, mutect2
- SYNE1 | c.61C>T p.L21= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV99559918; called by muse, mutect2, varscan2
- TAF6 | c.1224C>T p.D408= | Silent (SNP) | VAF 25/43 reads (58%) | catalogued as rs148894017; called by muse, mutect2, varscan2
- TBC1D22B | c.513C>T p.N171= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as rs755914209, COSV65143160; called by muse, mutect2, varscan2
- TENM2 | c.3393G>A p.A1131= (on ENST00000518659 / NM_001122679.2; = p.A899= on NM_001080428.3) | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as rs375058000; called by muse, mutect2, varscan2
- TESK1 | c.876C>T p.H292= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV99427378; called by muse, mutect2, varscan2
- TFE3 | c.1413G>A p.R471= | Silent (SNP) | VAF 38/83 reads (46%) | catalogued as COSV100252475; called by muse, mutect2, varscan2
- TFR2 | c.1527C>T p.N509= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as rs201943504, COSV56154592; ClinVar: likely benign; called by muse, mutect2, varscan2
- TGFBRAP1 | c.2019C>T p.H673= | Silent (SNP) | VAF 39/65 reads (60%) | catalogued as rs747923465, COSV99304956; called by muse, mutect2, varscan2
- TICAM1 | c.801G>A p.L267= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV99941070; called by muse, mutect2, varscan2
- TMCO6 | c.1131C>A p.S377= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as COSV99347108; called by muse, mutect2, varscan2
- TMEM101 | c.66G>A p.L22= | Silent (SNP) | VAF 16/29 reads (55%) | catalogued as COSV99243766; called by muse, mutect2, varscan2
- TMPO | c.381C>T p.Y127= | Silent (SNP) | VAF 40/84 reads (48%) | catalogued as rs370093524; called by muse, mutect2, varscan2
- TNFRSF25 | c.990G>A p.Q330= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV100556507; called by muse, mutect2, varscan2
- TRIM50 | c.129G>A p.L43= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as COSV99333900; called by muse, mutect2, varscan2
- TTBK1 | c.493C>T p.L165= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV99444202; called by muse, mutect2
- TUFM | c.999G>A p.K333= | Silent (SNP) | VAF 42/98 reads (43%) | catalogued as COSV100492491; called by muse, mutect2, varscan2
- TXNDC11 | c.1059G>A p.T353= (on ENST00000356957 / NM_001303447.2; = p.T326= on NM_015914.7 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as rs142448816, COSV51603619; called by muse, mutect2, varscan2
- UBE2J2 | c.489C>T p.V163= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as rs906399652, COSV100231118; called by muse, mutect2, varscan2
- UNC5B | c.1890C>T p.A630= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV58981905; called by muse, mutect2, varscan2
- UNC5D | c.1365C>T p.S455= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as rs766531280, COSV54801795; called by muse, mutect2, varscan2
- VASN | c.210C>T p.G70= | Silent (SNP) | VAF 24/46 reads (52%) | catalogued as rs1371728646, COSV99227478; called by muse, mutect2, varscan2
- VMO1 | c.180C>T p.S60= | Silent (SNP) | VAF 36/71 reads (51%) | catalogued as COSV99564647; called by muse, mutect2, varscan2
- WDFY3 | c.9933C>T p.P3311= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs563429345, COSV55699434; called by muse, mutect2, varscan2
- WDR3 | c.1512C>A p.L504= | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as COSV100832066; called by muse, mutect2, varscan2
- WDR6 | c.969G>A p.R323= | Silent (SNP) | VAF 20/36 reads (56%) | catalogued as COSV100556333; called by muse, mutect2, varscan2
- WNT3A | c.339C>T p.H113= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as rs377563839; called by muse, mutect2, varscan2
- ZBED1 | c.144C>T p.R48= | Silent (SNP) | VAF 66/139 reads (47%) | catalogued as rs1204247735, COSV100585428; called by muse, mutect2, varscan2
- ZBTB12 | c.444C>T p.S148= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs768825206, COSV100976973; called by muse, mutect2, varscan2
- ZC3H12C | c.2355C>T p.D785= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs1358630380, COSV53713792; called by muse, varscan2
- ZNF296 | c.804C>T p.C268= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as rs1006062076, COSV99673744; called by muse, mutect2, varscan2
- ZNF425 | c.1335G>A p.P445= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs950243260, COSV65200529; called by muse, mutect2, varscan2
- AC132217.2 | c.*46+1179G>A | Intron (SNP) | VAF 6/35 reads (17%) | catalogued as rs929796097, COSV100324001; called by muse, mutect2
- ACSS2 | c.834+816C>T | Intron (SNP) | VAF 33/73 reads (45%) | catalogued as COSV99489741, COSV99490303; called by muse, mutect2, varscan2
- AK9 | c.3633+13_3633+16del | Intron (DEL) | VAF 4/30 reads (13%) | catalogued as rs766264675; called by pindel, varscan2
- BCAS3 | c.2639-3349del | Intron (DEL) | VAF 12/24 reads (50%) | catalogued as rs756350876, COSV66772038; called by mutect2, varscan2
- BCL11A | c.386-6346C>T | Intron (SNP) | VAF 6/20 reads (30%) | catalogued as rs761041741, COSV100185342; called by muse, mutect2, varscan2
- C17orf58 | c.103+99del | Intron (DEL) | VAF 14/40 reads (35%) | called by mutect2, varscan2
- CCNQP1 | n.499C>T | RNA (SNP) | VAF 31/62 reads (50%) | called by muse, mutect2, varscan2
- CDKL1 | c.171+5554A>T | Intron (SNP) | VAF 20/51 reads (39%) | catalogued as COSV99367335; called by muse, mutect2, varscan2
- CR1 | c.488-15149A>G | Intron (SNP) | VAF 15/28 reads (54%) | catalogued as COSV100887523; called by mutect2, varscan2
- GNAO1 | c.723+7048C>T | Intron (SNP) | VAF 15/28 reads (54%) | catalogued as rs763880143, COSV99341017; called by muse, mutect2, varscan2
- HARS2 | c.-1G>A | 5'UTR (SNP) | VAF 10/28 reads (36%) | catalogued as rs1366769588, COSV100047609; called by muse, mutect2, varscan2
- KALRN | c.4929+22006G>A | Intron (SNP) | VAF 14/42 reads (33%) | catalogued as rs1271817050, COSV53762954; called by muse, mutect2, varscan2
- LDB3 | c.896+6738C>T | Intron (SNP) | VAF 12/22 reads (55%) | catalogued as rs377201153; ClinVar: uncertain significance; called by muse, varscan2
- NPHP4 | c.2611+492G>A | Intron (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- OSBPL6 | c.987+4533C>A | Intron (SNP) | VAF 23/60 reads (38%) | catalogued as COSV99507138; called by muse, mutect2, varscan2
- REG4 | c.*444dup | 3'UTR (INS) | VAF 9/28 reads (32%) | called by mutect2, pindel, varscan2
- SPEG | c.389-1507C>A | Intron (SNP) | VAF 13/28 reads (46%) | catalogued as COSV100404085; called by muse, mutect2, varscan2
- TAOK2 | chr16:29991441 G>A | 3'Flank (SNP) | VAF 9/23 reads (39%) | catalogued as rs1200489998, COSV99662950; called by muse, mutect2, varscan2
- THBD | c.*2C>T | 3'UTR (SNP) | VAF 16/28 reads (57%) | catalogued as COSV101001869; called by muse, mutect2, varscan2
- TRAC | c.*404del | 3'UTR (DEL) | VAF 23/50 reads (46%) | catalogued as rs754035003; called by mutect2, varscan2
- TUBB7P | n.97G>A | RNA (SNP) | VAF 15/33 reads (45%) | catalogued as rs781928065; called by muse, mutect2, varscan2
- UTP11 | c.*1C>T | 3'UTR (SNP) | VAF 18/46 reads (39%) | catalogued as rs746177102, COSV100884887; called by muse, mutect2, varscan2
